CPTAC case C3L-02348 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a404f9b8-278a-449f-ab02-3e97fd734e99

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1959; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 58.3 years (21,302 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T2b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,791 days (4.9 years); Progression or recurrence: no; Days to last follow up: 1,791 days (4.9 years); Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 6.5 cm (a second GDC size field records 3.2 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 13; Margin status: Uninvolved.

Follow-up (6 entries)
- Days to follow up: 378 days (1.0 years); Disease response: Tumor Free.
- Days to follow up: 697 days (1.9 years); Disease response: Tumor Free.
- Days to follow up: 1,070 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,425 days (3.9 years); Disease response: Complete Response.
- Days to follow up: 1,425 days (3.9 years); Disease response: Tumor Free.
- Days to follow up: 1,791 days (4.9 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 63 kg; Height: 152 cm; BMI: 27.27; DLCO (% of predicted): 71; FEV1/FVC after bronchodilator (%): 79; FEV1/FVC before bronchodilator (%): 67; FEV1 after bronchodilator (% of reference): 79; FEV1 before bronchodilator (% of reference): 78.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 71.8; Cigarettes per day: 35; Tobacco smoking onset year: 1976; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 46.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02348-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 273 mg.
- Sample C3L-02348-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 370 mg; Time between excision and freezing: 30 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02348-22: Section location: Right Lower Lobe; Percent tumor nuclei: 90; Percent necrosis: 2.
- Sample C3L-02348-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 319 mg; Time between excision and freezing: 30 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02348-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
